Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5092, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5092-01A (Primary Tumor).

AL DIAGNOSIS

NEY, LEFT, NEPHRECTOMY -

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE WITH EXTENSIVE MYXOID CHANGES.
- B. FUHRMAN NUCLEAR GRADE IS III OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 3.8 cm.
- D. THE NEOPLASM IS CONFINED WITHIN THE RENAL CAPSULE.
- E. NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- F. NO EVIDENCE OF ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- G. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- H. THE NON-NEOPLASTIC ADJACENT KIDNEY SHOWS FEATURES DUE TO PROXIMITY THE TUMOR.
- I. TNM STAGE: pT1a NX MX.

Source: NCI Genomic Data Commons file 515ab7e3-743d-4779-a5f5-4a0c6e44132a (TCGA-B0-5092.98AF808E-5C91-4F81-B0AF-2895AF96D4BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).